Gene-level copy-number profile of tumor specimen TCGA-VW-A8FI-01A from TCGA case TCGA-VW-A8FI, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Astrocytoma, anaplastic; Tissue or organ of origin: Cerebrum; Tumor grade: G3; Age at diagnosis: 66.8 years (24,411 days).
Specimen TCGA-VW-A8FI-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LGG.9215ecfa-b487-4788-9a13-e03131445f00.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-VW-A8FI-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/9e948a4d-4d2a-4daa-adfe-9819a09773dc

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 4,716; copy number 2: 51,762; copy number 3: 2,977; copy number 4: 135; copy number 5: 28; copy number 6: 5; copy number 7: 44; copy number 8: 27; copy number 9: 4; copy number 10: 59; copy number 12: 7; copy number 23: 34; copy number 26: 6; copy number 29: 10; copy number 37: 4.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-VW-A8FI-01A-11D-A36N-01): tumor purity 0.83, ploidy 2.03, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 228 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:22,364,630–23,344,336, 27 genes, copy number 8 (within-gene range 2–8): AL591122.1, ZBTB40, ZBTB40-IT1, EPHA8, MIR6127, C1QA, C1QC, C1QB, EPHB2, MIR4684, AL512444.1, MIR4253, LACTBL1, TEX46, KDM1A, AL031428.1, MIR3115, AL031428.2, LUZP1, AL161672.1, RNU6-514P, RNU6-135P, HTR1D, AL109936.1, LINC01355, AL109936.9, HNRNPR.
- chr4:46,734,827–47,426,447, 3 genes, copy number 5 (within-gene range 2–5): COX7B2, GABRA4, GABRB1.
- chr4:51,843,000–58,118,070, 127 genes, copy number 5–10 (broad region; genes not listed).
- chr7:54,185,071–55,211,628, 16 genes, copy number 23–37 (within-gene range 6–37): AC092848.2, AC092848.1, LINC01445, SLC25A5P3, VSTM2A, VSTM2A-OT1, AC011228.1, RNU6-1125P, RPL31P35, AC011228.3, AC011228.2, SEC61G, SEC61G-DT, AC006971.1, EGFR, EGFR-AS1.
- chr12:57,512,688–58,105,935, 45 genes, copy number 12–26: MIR6758, DDIT3, AC022506.1, MIR616, MBD6, DCTN2, KIF5A, PIP4K2C, DTX3, ARHGEF25, AC025165.1, AC025165.6, SLC26A10, B4GALNT1, RPL13AP23, OS9, AC025165.2, AGAP2, AGAP2-AS1, TSPAN31, CDK4, MIR6759, MARCHF9, CYP27B1, METTL1, EEF1AKMT3, AC025165.3, TSFM, AVIL, AC025165.5, RNU6-1083P, AC025165.4, CTDSP2, MIR26A2, AC083805.2, AC083805.1, AC083805.3, ATP23, GIHCG, AC084033.1, RN7SKP65, AC084033.2, LINC02403, AC090643.1, AC090643.2.
- chr15:25,580,969–26,134,001, 10 genes, copy number 7: AC023449.1, ATP10A, RNA5SP390, MIR4715, AC016266.1, LINC02346, AC044913.2, AC044913.1, AC100836.1, LINC00929.

Autosomal genes at a single copy (total copy number 1): 2,329. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
